Gene-level copy-number profile of tumor specimen TCGA-BF-A3DN-01A from TCGA case TCGA-BF-A3DN, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 81.6 years (29,801 days).
Specimen TCGA-BF-A3DN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.a06fecd1-567c-4c18-bfa2-5d058967cf04.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-A3DN-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/af5c7163-ce3f-4a46-a573-a1eef36e69ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2,683; copy number 2: 27,757; copy number 3: 21,885; copy number 4: 7,462; copy number 5: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-A3DN-01A-11D-A20B-01): tumor purity 0.75, ploidy 2.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:63,167,221–63,521,850, 1 gene (within-gene range 0–2): JMJD1C.
- chr10:63,358,745–63,625,128, 6 genes: AC022022.2, MIR1296, PRELID1P3, JMJD1C-AS1, AC022022.1, REEP3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 26 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:244,653,103–246,507,312, 26 genes, copy number 5 (within-gene range 3–5): DESI2, AL451007.1, AL451007.3, AL451007.2, BX323046.2, COX20, HNRNPU, BX323046.1, RN7SKP55, RNU6-947P, AL356512.1, EFCAB2, RNU6-1089P, RNU6-999P, AL589763.1, RNU1-132P, KIF26B, KIF26B-AS1, DNAJC19P8, AC104462.2, AC104462.1, SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P.

Autosomal genes at a single copy (total copy number 1): 262. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
